TCGA case TCGA-FD-A6TI — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - University Of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f956645-35aa-4a68-98d3-ea589459be00

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Dead; Days to death: 294 days.

Diagnoses (3)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.3; Tissue or organ of origin: Anterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 73.6 years (26,874 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic T: T4b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 294 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 21; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2c.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; Age at diagnosis: 73.7 years (26,914 days); Days to diagnosis: 40 days; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 40 days; Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 122 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 294.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 109 kg; Height: 155 cm; BMI: 45.4.

Exposures
- Occupation type: Building Frame and Related Trades Workers.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FD-A6TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,110 mg.
  Slide TCGA-FD-A6TI-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FD-A6TI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FD-A6TI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Retired; Occupation primary: Brick Layer; Tobacco smoking history indicator: 5; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Dome; Anatomic organ subdivision: Wall Anterior; Anatomic organ subdivision: Wall Lateral; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2c; New tumor event diagnosis indicator: No.
- Stage record, Gleason grading: Gleason score: 7.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: cystoprostatectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 294 days; disease-specific survival: no event (censored), 294 days; progression-free interval: no event (censored), 294 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FD-A6TI-01A-11D-A32A-01): tumor purity 0.5, ploidy 4.57, whole-genome doublings 2.
